Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4162, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4162-01A (Primary Tumor).

[page 1 of 2]
Other Related Data:

Billing Type:
Financial Number:

Clinical Diagnosis & History:

5 cm right renal tumor.

Specimens Submitted:

- 1: SP: Right kidney
- 2: SP: Paracaval lymph nodes
- 3: SP: Gallbladder

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE. NUCLEAR GRADE II/IV. THE PATTERN OF GROWTH IS ACINAR. THE TUMOR GREATEST DIAMETER IS 4.5 CM. THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY SHOWS BENIGN CYSTS.
- 2) LYMPH NODES, PARACAVAL; EXCISION:
- THREE LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).
- 3) GALLBLADDER; CHOLECYSTECTOMY:
- CHRONIC CHOLECYSTITIS AND CHOLELITHIASIS.

Gross Description:

- 1) The specimen is received fresh, labeled "Right kidney". It consists of a nephrectomy specimen. The entire specimen weighs 330 grams and measures 13 x 7 x 4 cm. Sectioning reveals a 4.5 cm circumscribed yellow somewhat friable tumor towards the upper pole. The tumor measures 4.5 cm in maximal dimension and is confined within the kidney. Multiple cysts are identified in the kidney with the largest measuring 4 cm towards the upper pole. The cysts are lined by smooth glistening lining and contains

[page 2 of 2]
clear fluid. The uninvolved kidney appears unremarkable with prominent cortical medullary junction. The tumor does not extend into the renal pelvis. There is no evidence of invasion of renal vein grossly. Representative sections are submitted.

Summary of Sections:

T - tumor
TK - tumor with kidney
TC - tumor with capsule
C - representative sections of cyst
K - uninvolved kidney
GF - Gerota's fascia
UM - ureteric margin
VM - vascular margin
HF - hilar fat

2) The specimen is received in formalin, labeled "Paracaval lymph nodes". It consists of fatty tissue with multiple lymph nodes with the largest measuring 2 cm. All lymph nodes are submitted.

Summary of Sections:

LNB - bisected lymph nodes
LN - multiple lymph nodes

3) The specimen is received in formalin, labeled "Gallbladder". It consists of a gallbladder measuring 7 x 3.5 x 2 cm. The specimen has previously been opened to reveal multiple black irregular gallstones measuring from 2.0 to 0.5 cm. The gallbladder wall measures 0.3 cm in thickness. The mucosa is green and granular with no gross lesions. Representative sections are submitted.

Summary of section:

U - undesignated

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	C		2	M	
	GF		1	M	
	HF		2	M	
	K		1	M	
	T		2	M	
	TC		1	M	
	TK		1	M	
	UM		1	M	
	VM		1	M	
2	LN		1	2	
	LNB		1	3	
3	U		1	3	

Source: NCI Genomic Data Commons file 05ed4f5b-a7d9-4949-95a9-e6599385bf17 (TCGA-BP-4162.38B98D39-B206-4A74-8311-5950F14E5BC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).